Somatic mutation profile of tumor specimen MP2PRT-PAWCRT-TBP1-A (aliquot MP2PRT-PAWCRT-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAWCRT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,409 days).
Specimen MP2PRT-PAWCRT-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6ac3c426-7939-49e3-9f9d-71bedcf61660.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWCRT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWCRT-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/228e1a3b-ed1c-459e-8033-1e8b69e60f38

The open-access MAF lists 9 somatic variants for this specimen: 5 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.227A>C p.E76A | Missense Mutation (SNP) | VAF 26/476 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as rs121918465, CM112765, CM1314032, CM137734, COSV61005372, COSV61006382, COSV61007426; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ARHGEF10L | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 46/506 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as rs773332883; called by muse, mutect2
- KRT75 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 25/300 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs201872427, COSV52873636, COSV99359174; called by muse, mutect2
- RLIM | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 42/760 reads (6%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.996); catalogued as rs767880629, COSV100223083; called by muse, mutect2
- ARHGEF10 | c.4082T>A p.V1361D (on ENST00000398564; = p.V1336D on NM_014629.4) | Missense Mutation (SNP) | VAF 38/691 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- GPR37 | c.1314C>T p.Y438= | Silent (SNP) | VAF 26/526 reads (5%) | catalogued as rs368914982; called by muse, mutect2
- IGSF9B | c.420C>A p.T140= | Silent (SNP) | VAF 20/335 reads (6%) | called by muse, mutect2
- PLXNA3 | c.1590C>T p.H530= | Silent (SNP) | VAF 36/927 reads (4%) | catalogued as rs201953943, COSV63754524; called by muse, mutect2
- RPS6KA2 | c.672G>A p.E224= | Silent (SNP) | VAF 111/695 reads (16%) | catalogued as rs759445973; called by muse, mutect2, varscan2
